Somatic mutation profile of tumor specimen TARGET-10-PARAKF-04A (aliquot TARGET-10-PARAKF-04A-01D) from TARGET case TARGET-10-PARAKF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,051 days).
Specimen TARGET-10-PARAKF-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e85aaa1-9766-44d4-b9cc-224cc9e287cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAKF-10A (Blood Derived Normal), aliquot TARGET-10-PARAKF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e5f2829-bc25-45c0-ba66-5a17f84650c9

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4244C>A p.T1415K (on ENST00000272895 / NM_173076.3; = p.T1097K on NM_015657.3) | Missense Mutation (SNP) | VAF 167/501 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.138); catalogued as COSV55950925; called by muse, mutect2, varscan2
- CDHR1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 74/191 reads (39%) | catalogued as rs191858417, CM156177, COSV60559927; called by muse, mutect2, varscan2
- DMKN | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs373879312; called by muse, mutect2, varscan2
- DSCAM | c.5624C>A p.P1875H | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68021936; called by muse, mutect2, varscan2
- GOLGA6A | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs542174200, COSV51804412; called by muse, mutect2, varscan2
- MARCKS | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV64042590; called by muse, mutect2, varscan2
- MLPH | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs372579688, COSV99222543; called by muse, mutect2
- PCDHA6 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.259); catalogued as COSV67034078, COSV67044410; called by muse, mutect2, varscan2
- PCDHB4 | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52019999; called by muse, mutect2, varscan2
- PRAMEF20 | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1448822953; called by muse, mutect2
- RP1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV55111361; called by muse, mutect2, varscan2
- SNTB1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs753694409, COSV67324796; called by muse, mutect2, varscan2
- TNNT2 | c.233+3G>A | Splice Region (SNP) | VAF 89/181 reads (49%) | catalogued as rs113624085, COSV52661175; called by muse, mutect2, varscan2
- ZFYVE28 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs765407347, COSV52108148; called by muse, mutect2, varscan2
- ZNF536 | c.1051G>C p.G351R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62819589, COSV62820183, COSV62820593; called by muse, mutect2, varscan2
- ABTB2 | c.921C>T p.N307= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs147993026; called by muse, mutect2, varscan2
- ATP8A2 | c.1290T>G p.T430= | Silent (SNP) | VAF 350/833 reads (42%) | catalogued as COSV54939630; called by muse, mutect2, varscan2
- ELAVL2 | c.813C>T p.H271= | Silent (SNP) | VAF 92/215 reads (43%) | catalogued as COSV56358160; called by muse, mutect2, varscan2
- PCDHA4 | c.2118G>A p.A706= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs782718692, COSV63539392; called by muse, mutect2, varscan2
- PGAP2 | c.186G>A p.S62= (on ENST00000463452 / NM_001346398.2; = p.S123= on NM_014489.4) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs754872436, COSV53464202; called by muse, mutect2, varscan2
- SLC17A7 | c.498C>T p.R166= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV55546745, COSV99677069; called by muse, mutect2, varscan2
- SOX6 | c.1191G>A p.T397= (on ENST00000528429 / NM_001145819.2; = p.T356= on NM_017508.3) | Silent (SNP) | VAF 218/561 reads (39%) | catalogued as rs139974161, COSV57044852; called by muse, mutect2, varscan2
- LTN1 | chr21:28992912 C>G | 5'Flank (SNP) | VAF 19/53 reads (36%) | catalogued as COSV57478218; called by muse, mutect2, varscan2
